Somatic mutation profile of tumor specimen MBCProject_1554_T1_WES (aliquot MBCProject_1554_T1_WES_1) from CMI case MBCProject_1554, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.2 years (19,416 days).
Specimen MBCProject_1554_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone Marrow; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5a5fe82-703a-4116-a33b-800bef5e361e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1554_SALIVA (Saliva), aliquot MBCProject_1554_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d8d4631-c9c6-4fbc-9e1c-0e57c1dd3ddc

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 13, Nonsense Mutation 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 45/211 reads (21%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- GBP1 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs375266486; called by muse, mutect2, varscan2
- JAG2 | c.3350G>A p.R1117Q | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as rs747444035; called by muse, mutect2, varscan2
- OIT3 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV61825739; called by muse, mutect2, varscan2
- PRAMEF27 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 123/577 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1244279328; called by muse, mutect2, varscan2
- PRKCZ | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.433); catalogued as rs763191925; called by muse, mutect2, varscan2
- RASA1 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1191737466; called by mutect2, varscan2
- TEX47 | c.520T>A p.F174I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs755787489; called by muse, varscan2
- AP2A1 | c.918_919del p.N307Rfs*14 | Frame Shift Del (DEL) | VAF 70/498 reads (14%) | called by mutect2, pindel, varscan2
- CPNE8 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 62/419 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFHB | c.1688T>A p.F563Y | Missense Mutation (SNP) | VAF 63/348 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HPS3 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGF2R | c.7312G>T p.A2438S | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGAD | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- KLHL34 | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, varscan2
- NTRK3 | c.215A>T p.N72I | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- PIWIL2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PLEKHD1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPARG | c.175T>G p.S59A (on ENST00000287820 / NM_015869.5; = p.S29A on NM_005037.7) | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL2 | c.1037C>A p.P346Q | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SPARCL1 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13D | c.11410G>A p.E3804K | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BRPF3 | c.1119C>A p.T373= | Silent (SNP) | VAF 62/319 reads (19%) | called by muse, mutect2, varscan2
- DLG5 | c.3882G>T p.V1294= | Silent (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2
- DUS3L | c.330G>A p.R110= | Silent (SNP) | VAF 85/457 reads (19%) | called by muse, mutect2, varscan2
- FMN2 | c.1389C>T p.A463= | Silent (SNP) | VAF 56/188 reads (30%) | catalogued as COSV100147908; called by muse, mutect2, varscan2
- GGT7 | c.1650C>T p.P550= | Silent (SNP) | VAF 39/382 reads (10%) | catalogued as rs576222899, COSV100321711, COSV60542484; called by muse, mutect2, varscan2
- H2BC13 | c.198C>T p.F66= | Silent (SNP) | VAF 77/465 reads (17%) | called by muse, mutect2, varscan2
- KCNH4 | c.1458G>A p.S486= | Silent (SNP) | VAF 76/423 reads (18%) | catalogued as rs777330774; called by muse, mutect2, varscan2
- KRTAP29-1 | c.720C>T p.C240= | Silent (SNP) | VAF 49/280 reads (18%) | called by muse, mutect2, varscan2
- LRRIQ4 | c.621C>T p.I207= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as COSV100540143, COSV61619163; called by muse, mutect2, varscan2
- MAGEA6 | c.63G>A p.E21= | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2, varscan2
- PRSS1 | c.435C>A p.G145= | Silent (SNP) | VAF 99/445 reads (22%) | called by muse, mutect2, varscan2
- RYR1 | c.6309G>A p.V2103= | Silent (SNP) | VAF 65/327 reads (20%) | called by muse, mutect2, varscan2
- TDRD15 | c.531C>G p.L177= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1021+893dup | Intron (INS) | VAF 4/40 reads (10%) | catalogued as rs1351063893; called by pindel, varscan2
